Somatic mutation profile of tumor specimen C3N-03488-03 (aliquot CPT0194250009) from CPTAC case C3N-03488, project CPTAC-3 (Other and ill-defined sites — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-03488-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Sinus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df2f605d-8ccb-4b84-8d34-9073738a4783.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03488-71 (Blood Derived Normal), aliquot CPT0194350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcc367b1-36ee-4cb5-8cce-8051d2f1d11e

The open-access MAF lists 154 somatic variants for this specimen: 113 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 24, Intron 7, Nonsense Mutation 5, 5'UTR 4, Frame Shift Ins 3, RNA 3, 3'UTR 2, Splice Site 1, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH4A1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs139430775; called by muse, mutect2, varscan2
- ANGEL1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 70/681 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs370876261; called by muse, mutect2, varscan2
- ASXL3 | c.5989A>G p.K1997E | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs997568581; called by muse, mutect2, varscan2
- BAIAP2L2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs747122032; called by muse, mutect2, varscan2
- CACNA1I | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100359418; called by muse, varscan2
- CELF4 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as rs765103903, COSV58450078; called by muse, mutect2, varscan2
- COL11A2 | c.2482C>T p.R828W (on ENST00000341947 / NM_080680.3; = p.R721W on NM_080679.2) | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs752629970; called by muse, mutect2, varscan2
- DCAF12L2 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV63582317; called by muse, varscan2
- DEGS2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480686517, COSV59784269; called by muse, mutect2, varscan2
- DNAJC17 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV53067117; called by muse, mutect2, varscan2
- DPYSL5 | c.1177C>A p.R393S | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV56509257; called by muse, mutect2, varscan2
- ESRRG | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV63165308; called by muse, mutect2, varscan2
- GRM5 | c.2956G>A p.G986S (on ENST00000305447 / NM_001143831.2; = p.G954S on NM_000842.4) | Missense Mutation (SNP) | VAF 175/352 reads (50%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1347264554; called by muse, mutect2, varscan2
- GYG1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 41/508 reads (8%) | catalogued as rs777291159, COSV99936855; called by muse, mutect2
- IGF1R | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1225857187, COSV99163002; called by muse, mutect2, varscan2
- ITGA1 | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV50884215; called by muse, mutect2, varscan2
- ITPR1 | c.5257C>T p.R1753* (on ENST00000354582; = p.R1698* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 42/218 reads (19%) | catalogued as COSV56968801; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 61/496 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); catalogued as rs1178247283; called by muse, mutect2, varscan2
- MAST2 | c.4750G>A p.G1584R | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs369600489; called by muse, mutect2, varscan2
- MGAM | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.238); catalogued as rs371373847; called by muse, mutect2, varscan2
- MUC12 | c.1459C>A p.P487T (on ENST00000379442; = p.P344T on NM_001164462.1) | Missense Mutation (SNP) | VAF 169/356 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.905); catalogued as rs865913396; called by muse, varscan2
- MYLK2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs763316056, COSV65660170; called by muse, mutect2, varscan2
- NDUFA6 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 156/490 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as CM109887; called by muse, mutect2, varscan2
- NLRP2 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 33/436 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV54753138; called by muse, mutect2
- NPC1L1 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755881757, CM068042, COSV99202550; called by muse, mutect2
- NUP107 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs761403730; called by muse, mutect2, varscan2
- OR51Q1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371190479, COSV56177770; called by muse, mutect2, varscan2
- OR8J3 | c.708dup p.A237Sfs*35 | Frame Shift Ins (INS) | VAF 12/87 reads (14%) | catalogued as rs1214882553; called by mutect2, pindel, varscan2
- PIF1 | c.450C>G p.I150M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51423552; called by muse, mutect2, varscan2
- POFUT2 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs530089816; called by muse, mutect2, varscan2
- PRAM1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99725492; called by muse, mutect2, varscan2
- RGS18 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV66508763; called by muse, mutect2, varscan2
- RIMBP2 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as rs147262074, COSV99898187; called by muse, mutect2, varscan2
- SAFB | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.112); catalogued as rs756589107, COSV52651292, COSV52652226, COSV52653358; called by muse, mutect2, varscan2
- SCN1A | c.2884G>A p.V962I (on ENST00000303395 / NM_001202435.3; = p.V951I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/403 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57680029; called by muse, mutect2, varscan2
- SEMA3E | c.122T>C p.L41S | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs778519947; called by muse, mutect2, varscan2
- SMAD4 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555685186, COSV61685472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.4256C>T p.A1419V | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs1413620647; called by muse, mutect2, varscan2
- SON | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV51658578; called by muse, mutect2, varscan2
- SPG11 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1440947266; called by muse, mutect2, varscan2
- THSD7B | c.4693G>A p.G1565S (on ENST00000272643; = p.G1563S on NM_001316349.2) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55698813; called by muse, mutect2, varscan2
- TTN | c.67220G>A p.R22407K (on ENST00000591111; = p.R14983K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | PolyPhen benign (0); catalogued as COSV59863511; called by muse, mutect2, varscan2
- UMOD | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56776363; called by muse, mutect2, varscan2
- XKR5 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as rs376128988; called by muse, mutect2, varscan2
- ZBED4 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as rs756748204, COSV53468362; called by muse, mutect2, varscan2
- ZNF277 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs777119591, COSV100702294, COSV62464397; called by muse, mutect2, varscan2
- ZNF324 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs779265268; called by muse, mutect2, varscan2
- ZNF331 | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53476931; called by muse, mutect2, varscan2
- ZNF469 | c.5668G>A p.G1890S (on ENST00000437464; = p.G1918S on NM_001367624.2) | Missense Mutation (SNP) | VAF 116/380 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs1331518805; called by muse, mutect2, varscan2
- ZNF484 | c.2135G>T p.R712I | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs772453518, COSV60256677; called by muse, mutect2, varscan2
- ZNF844 | c.879C>G p.F293L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101462744; called by muse, mutect2, varscan2
- ABCA13 | c.1778C>G p.T593S | Missense Mutation (SNP) | VAF 21/703 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- AGAP6 | c.1216G>T p.E406* (on ENST00000374056 / NM_001365867.1; = p.E429* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 86/726 reads (12%) | called by muse, mutect2, varscan2
- BTBD8 | c.3739A>C p.S1247R (on ENST00000636805 / NM_001376131.1; = p.S734R on NM_015237.4) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC191 | c.907dup p.M303Nfs*37 | Frame Shift Ins (INS) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- CCDC25 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by mutect2, varscan2
- CCN2 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.031); called by muse, mutect2
- CKAP2 | c.1126G>A p.A376T (on ENST00000378037 / NM_001098525.2; = p.A375T on NM_018204.5) | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CPSF3 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DAZL | c.453T>A p.Y151* | Nonsense Mutation (SNP) | VAF 63/143 reads (44%) | called by muse, mutect2, varscan2
- DIS3 | c.1907A>C p.E636A | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNHD1 | c.6905+8C>A | Splice Region (SNP) | VAF 75/209 reads (36%) | called by muse, mutect2, varscan2
- DPY19L4 | c.1335-1G>A p.X445_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- FANCA | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 84/549 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FBXO21 | c.1099A>T p.I367F | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXP2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 122/400 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- GLB1 | c.1612G>C p.A538P | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLT1D1 | c.676T>A p.L226M (on ENST00000442111 / NM_001366889.1; = p.L146M on NM_144669.3) | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- HMGB2 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HYKK | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRAK3 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGA1 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 231/376 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- KCNA4 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNB1 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYG2 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCAPH2 | c.1543T>C p.F515L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NCBP2 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- NLRP3 | c.2840A>G p.D947G | Missense Mutation (SNP) | VAF 123/387 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NOTCH1 | c.6467A>G p.K2156R | Missense Mutation (SNP) | VAF 211/403 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NOTCH2 | c.5554G>T p.E1852* | Nonsense Mutation (SNP) | VAF 124/290 reads (43%) | called by muse, mutect2, varscan2
- NRK | c.3230T>A p.L1077H | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE1 | c.584C>T p.A195V (on ENST00000424269; = p.A53V on NM_152315.5) | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR14A2 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4K5 | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPSS1 | c.1230G>C p.M410I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PCDHA12 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PFKFB3 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PKHD1L1 | c.12380T>C p.L4127P | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- RELN | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 90/558 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, varscan2
- RGL4 | c.276del p.F92Lfs*19 | Frame Shift Del (DEL) | VAF 39/296 reads (13%) | called by mutect2, pindel, varscan2
- RNF133 | c.554T>A p.I185N | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SAMD9L | c.2670G>T p.M890I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SCN1A | c.5069C>T p.S1690F (on ENST00000303395 / NM_001202435.3; = p.S1679F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SIN3A | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SQLE | c.889T>A p.S297T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TM6SF2 | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOX3 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 185/670 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TP53 | c.1034dup p.N345Kfs*2 | Frame Shift Ins (INS) | VAF 139/328 reads (42%) | called by mutect2, pindel, varscan2
- TRIM33 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TYMS | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- USPL1 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- VARS1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZBED9 | c.2169A>T p.E723D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB37 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZFP28 | c.1495C>A p.H499N | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF195 | c.1599G>C p.Q533H (on ENST00000399602 / NM_001130520.3; = p.Q461H on NM_007152.5) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZNF276 | c.1448A>T p.Q483L (on ENST00000443381 / NM_001113525.2; = p.Q408L on NM_152287.4) | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF358 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ZNF479 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 157/476 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF567 | c.1906C>G p.Q636E (on ENST00000536254 / NM_001322913.1; = p.Q605E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF90 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSCAN1 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSWIM5 | c.69T>G p.C23W | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ATP2A1 | c.408A>C p.S136= | Silent (SNP) | VAF 20/470 reads (4%) | called by muse, mutect2
- CPXM1 | c.1407C>A p.T469= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV66044881; called by muse, mutect2, varscan2
- CYP4F3 | c.1257C>T p.I419= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- EIF4G1 | c.3534G>T p.R1178= (on ENST00000346169 / NM_198241.3; = p.R983= on NM_004953.5) | Silent (SNP) | VAF 186/728 reads (26%) | called by muse, mutect2, varscan2
- FREM2 | c.9333G>C p.L3111= | Silent (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- FRMD1 | c.1389C>T p.S463= | Silent (SNP) | VAF 32/242 reads (13%) | catalogued as rs753435160, COSV51964056; called by muse, mutect2, varscan2
- GRM8 | c.2112C>A p.S704= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs765177458, COSV100279382, COSV58877631; called by muse, mutect2, varscan2
- HSD17B1 | c.252C>T p.R84= | Silent (SNP) | VAF 89/504 reads (18%) | catalogued as rs1292636952; called by muse, mutect2, varscan2
- LAMA5 | c.9441C>G p.V3147= | Silent (SNP) | VAF 244/723 reads (34%) | called by muse, mutect2, varscan2
- MYO1F | c.1416C>T p.G472= | Silent (SNP) | VAF 54/302 reads (18%) | catalogued as rs770980207; called by muse, mutect2, varscan2
- NLRP1 | c.2394G>A p.Q798= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV52578662; called by muse, mutect2, varscan2
- OR51B5 | c.546C>G p.V182= | Silent (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- OR9G1 | c.198G>A p.S66= | Silent (SNP) | VAF 51/438 reads (12%) | catalogued as rs778129132, COSV56448890; called by muse, mutect2, varscan2
- PADI4 | c.678C>T p.S226= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs145309015; called by mutect2, varscan2
- PLCB3 | c.3117G>C p.V1039= | Silent (SNP) | VAF 22/343 reads (6%) | called by muse, mutect2
- PRR12 | c.483C>A p.P161= (on ENST00000615927; = p.P982= on NM_020719.3) | Silent (SNP) | VAF 46/285 reads (16%) | catalogued as rs1448459843; called by muse, mutect2, varscan2
- QRICH2 | c.1938G>A p.V646= | Silent (SNP) | VAF 60/548 reads (11%) | called by muse, varscan2*
- RANBP17 | c.781T>C p.L261= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1412735632; called by muse, mutect2
- SBF1 | c.4497C>T p.A1499= | Silent (SNP) | VAF 81/274 reads (30%) | catalogued as rs377500587; called by muse, mutect2, varscan2
- SF1 | c.450C>T p.I150= | Silent (SNP) | VAF 34/482 reads (7%) | catalogued as COSV57112897; called by muse, mutect2
- SHANK1 | c.5541G>T p.P1847= | Silent (SNP) | VAF 92/281 reads (33%) | catalogued as COSV53245669; called by muse, mutect2, varscan2
- SLC24A3 | c.501G>A p.S167= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs762736740; called by muse, mutect2, varscan2
- SRSF4 | c.642T>C p.S214= | Silent (SNP) | VAF 27/261 reads (10%) | called by muse, mutect2, varscan2
- WBP2NL | c.750C>T p.L250= | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as rs143530198; called by muse, mutect2, varscan2
- AC000120.2 | c.-361G>A | 5'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- ADCY4 | c.357+18C>A | Intron (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- ATP2A1 | c.*165_*176del | 3'UTR (DEL) | VAF 35/198 reads (18%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1771-23G>A | Intron (SNP) | VAF 62/349 reads (18%) | catalogued as rs776454193, COSV52564104; called by muse, mutect2, varscan2
- DCUN1D4 | c.414+515T>G | Intron (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- DSG4 | c.2138-57G>A | Intron (SNP) | VAF 26/149 reads (17%) | catalogued as rs1323497124, COSV100355781; called by muse, mutect2, varscan2
- FAM13C | c.62+1313T>C | Intron (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- HSPE1-MOB4 | c.-7G>C | 5'UTR (SNP) | VAF 66/313 reads (21%) | called by muse, mutect2, varscan2
- KITLG | c.-59A>G | 5'UTR (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- MIF4GD | chr17:75272184 G>C | 5'Flank (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- POLG | c.2982-51C>T | Intron (SNP) | VAF 38/242 reads (16%) | catalogued as rs201474278; called by muse, mutect2, varscan2
- PTGS2 | c.-1G>T | 5'UTR (SNP) | VAF 32/210 reads (15%) | called by muse, mutect2, varscan2
- RASSF6 | c.63-4086C>T | Intron (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- SMG1P3 | n.513A>G | RNA (SNP) | VAF 18/388 reads (5%) | called by muse, mutect2
- SSPOP | n.6876C>T | RNA (SNP) | VAF 30/227 reads (13%) | catalogued as rs373074929; called by muse, mutect2, varscan2
- SVIL2P | n.1365G>A | RNA (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- TAFA5 | c.*27G>T | 3'UTR (SNP) | VAF 37/209 reads (18%) | called by muse, varscan2
